Somatic mutation profile of tumor specimen 0D9K4U from CCDI case PBBIDL, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Neoplasm, metastatic; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 0.9 years (332 days).
Specimen 0D9K4U: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fb3a0df5-b4ca-446f-b5b2-145adaec74bb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0D9K4V (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8471dea4-f7f9-4360-bd36-e727b5167bf2

The open-access MAF lists 1 somatic variant for this specimen: 1 protein-altering or splice-affecting.
By variant classification: Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ECSIT | c.353G>A p.R118Q | Missense Mutation (SNP) | VAF 255/515 reads (50%) | SIFT tolerated (0.19); PolyPhen benign (0.33); catalogued as rs778037100, COSV52939464; called by muse, mutect2, varscan2
